Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A1AB, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A1AB-01A (Primary Tumor).

[page 1 of 6]
ICD - 0 - 3

Carcinoma, urothelial, NOS 8120/3

Site Code: bladder, NOS C67.9

12/30/10
JW**SURGICAL PATHOLOGY REPORT****Patient Name:****Med. Rec. #:**

DOB: (

Gender:

F

Ref. Physician:

Patient Address:

Location:

Service: Urology

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

INPATIENT

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Muscle invasive urothelial cell carcinoma.

Specimens Submitted:

- 1: SP: Bladder, cervix, bilateral tubes and ovaries; Cystohysterectomy and bilateral salpingo-oophorectomy
- 2: SP: Right pelvic lymph nodes; Dissection
- 3: SP: Left pelvic lymph nodes; Dissection
- 4: SP: Left peri-ureteral tissue; Excision
- 5: SP: Distal margin of urethra; Excision
- 6: SP: Posterior vaginal wall; Excision
- 7: SP: Left ureter; Excision
- 8: SP: Right ureter; Excision

DIAGNOSIS:
1. BLADDER, CERVIX, BILATERAL FALLOPIAN TUBES AND OVARIES; CYTOHYSTERECTOMY AND BILATERAL
SALPINGO-OOPHERECTOMY
TUMOR #1

- INVASIVE UROTHELIAL CARCINOMA, NOS, HIGH GRADE OF THE BLADDER
- FOCAL CARCINOMA IN SITU, ALTHOUGH COLONIZATION OF MUCOSA BY UNDERLYING INVASIVE CARCINOMA CANNOT BE ENTIRELY EXCLUDED
- TUMOR INVOLVES THE FOLLOWING EXTRAVESICAL STRUCTURES: LEFT URETER (PART 7), PERIVESICAL FAT, UTERUS (MYOMETRIUM AND ENDOMETRIUM), SUBMUCOSAL CERVIX TISSUE, DEEP SOFT TISSUE OF ANTERIOR VAGINAL WALL
- THERE IS EXTENSIVE PERINEURAL AND LYMPHOVASCULAR INVASION
- THE NON-NEOPLASTIC MUCOSA SHOWS FOREIGN BODY GIANT REACTION
- THE SURGICAL MARGINS ARE FREE OF TUMOR
- THE URETERAL UROTHELIUM IS BENIGN
- PERIVESICAL LYMPH NODES ARE NOT IDENTIFIED
- AJCC STAGING (2002): PT4 (INVASION OF UTERUS OR VAGINA)

TUMOR #2

- SEROUS CARCINOMA, HIGH GRADE, OF MULLERIAN ORIGIN
- TUMOR DISTRIBUTION AND PRESENCE OF TUMOR MASS IN RIGHT FIMBRIA SUGGESTS ORIGIN IN RIGHT FALLOPIAN TUBE
- OTHER SITES OF TUMOR INVOLVMENT INCLUDE THE SURFACES OF THE RIGHT AND LEFT OVARY, SEROSAL SURFACE OF THE LEFT URETER (SEE PART 7), PERIURETERAL TISSUE (SEE PART 4), AND SUBSEROSAL TISSUE OF THE BLADDER
- THE NON-NEOPLASTIC OVARIAN TISSUE SHOWS INCLUSION CYSTS
- THE NON-NEOPLASTIC MYOMETRIUM SHOWS LEIOMYOMATA

NOTE: IMMUNOHISTOCHEMICAL STAINS ARE PERFORMED. THE UROTHELIAL CARCINOMA IS POSITIVE FOR P63, AND 34BE12, CK7 (FOCAL) AND P16 (WEAK, FOCAL); WHILE NEGATIVE FOR PAX 8, P53, CK20, ER, PR AND WT1. THE SEROUS CARCINOMA IS POSITIVE FOR WT-1, P16, PAX8, CK7, 34BE12 (FOCAL), AND ER WHILE NEGATIVE FOR P53, P63, CK20, AND PR. THE TWO TUMORS SHOW DIFFERENT STAINING PROFILES WHICH SUPPORTS THE DIAGNOSIS. REPRESENTATIVE SECTIONS ARE SHOWN IN CONSULTATION TO F

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

2. SP: Right pelvic lymph nodes; Dissection:

Lymph Node Dissection:

Metastatic Urothelial carcinoma

Number of lymph nodes examined: 7

Number of lymph nodes with metastatic disease: 1

Extranodal extension is not identified

3. SP: Left pelvic lymph nodes; Dissection:

Lymph Node Dissection:

Metastatic urothelial carcinoma involves one lymph node and metastatic serous carcinoma involves two lymph nodes; A total of 7 lymph nodes examined.

4. PERI-URETERAL TISSUE, LEFT; EXCISION:

- METASTATIC SEROUS CARCINOMA

5. URETHA, DISTAL MARGIN; EXCISION:

- BENIGN URETHRA TISSUE

6. VAGINAL WALL, POSTERIOR; EXCISION:

-BENIGN FRAGMENT OF FIBROUS TISSUE

7. URETER, LEFT; EXCISION:

- INVASIVE UROTHELIAL CARCINOMA INVOLVING THE MUSCULARIS PROPRIA AND SUBSEROUSAL SOFT TISSUE OF THE URETER; THE URETERAL MUCOSAL SURFACE IS BENIGN.

- METASTATIC SEROUS CARCINOMA INVOLVING THE SEROUSAL SURFACE OF THE URETER

8. URETER, RIGHT; EXCISION:

- BENIGN SEGMENT OF URETER

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result Spec	al Stain	Comment
P53		
ER.		
PR		
CK7		
CK20		
WT	1	
PAX8.		
3	4BE12	
4A4/P63		
P16.		
NEG	CONT	
IMM	RECUT	

Gross Description:

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

1. The specimen is received fresh labeled, "Bladder, uterus, cervix, urachus, urethra, bilateral tubes and ovaries, anterior vaginal wall, perivesical fat". It consists of a cystohysterectomy with bilateral salpingo-oophorectomy specimen measuring 16 cm from superior to inferior, 12 cm laterally and 5.5 cm from anterior to posterior. The uterus measures 7.0 cm superior to inferior, 5.0 cm from cornu to cornu, and 3.0 from anterior to posterior. There is a subserosal 3.0 cm anterior nodule which is partially calcified. There are two intramural nodules measuring 0.8 and 1.7 cm in greatest dimension. The cut surfaces are white and whorled. The right ovary measures 2.5 x 1.8 x 1.8 cm and is partially cystic. The right fallopian tube measures 6 cm in length with an altered fimbriated end. There are approximately four paratubal cysts measuring 0.4 cm in greatest dimension. The left ovary measures 2.5 x 1.2 x 1.0 cm. The left fallopian tube measures 5.5 cm in length with a normal fimbriated end. There are several, approximately 7 paratubal cysts ranging in size from 0.1 to 1.0 cm in greatest dimension. The cervix measures 3.2 cm in length and the ectocervix measures 2.5 cm in diameter. The right aspect of the bladder is inked green and the left aspect of bladder is inked blue. The uterus is inked black posteriorly. The urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal an oval shaped ulcerated, fungating lesion measuring 3.5 x 2.5 cm on the posterior wall and trigone. The lesion appears to be involving the both ureteral orifices. Both ureters are probe patent measuring up to 0.2 cm in maximum diameter. The lesion is sectioned and revealed that the lesion is superficial without penetrating through the deep muscularis layer and the underlying fat grossly. Extension to the inked fat is grossly not identified. The remaining bladder mucosa is pink and edematous. Discrete perivesical lymph nodes are grossly not identified. The entire lesion is submitted and representative sections from the rest of the bladder are submitted. The ovaries and fallopian tubes are submitted entirely. TPS is submitted. Photographs are taken.

Summary of sections:

RUM - right ureter margin

LUM - left ureter margin

UTHM - urethral margin

L - lesion

L4-7-lesion to anterior cervix

L8-9-lesion to posterior bladder serosa and anterior uterus

RUO - right ureter orifice

LUO - left ureter orifice

LA - left anterior wall

LP - left posterior wall

RP - right posterior wall

RA - right anterior wall

DOM - dome

F - perivesical fat

AC- anterior cervix

PC - posterior cervix

AEM - anterior endometrium

PEM - posterior endometrium

RO - right ovary

RT - right tube

LO - left ovary

LT - left tube

ADD - additional sections of ovary, submitted entirely

ADD27-28- right ovary

ADD29-30- left ovary

T - additional sections of tube, unknown laterality

2). The specimen is received fresh, labeled "right pelvic lymph nodes, fresh and sterile" and consists of multiple pink tan firm lymph nodes ranging from 1.2 to 5.7 cm in greatest dimension. All identified lymph nodes are submitted in twelve cassettes.

Summary of sections:

LN - lymph nodes

BLN - bisected lymph nodes

RSLN - representative sections lymph node

3). The specimen is received fresh, labeled "left pelvic lymph nodes, fresh and sterile" and consists of multiple pink tan firm lymph nodes. All identified lymph nodes are submitted in sixteen cassettes.

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

Summary of sections:

LN - lymph nodes
BLN - bisected lymph nodes
SLN - sectioned lymph node
RSLN - representative sections lymph node

4.) The specimen is received in formalin, labeled "Left periureteral tissue" and consists of a 1.3 x 1.1 x 0.3 cm, soft, irregular, pink-white fiber membranous tissue fragment with attached underlying adipose. The surface is partially covered by a 1.0 x 0.6 x 0.1 cm, slightly raised, irregular, tan-purple nodular lesion. The specimen is sectioned and entirely submitted.

Summary of sections:

LPT - left perirectal tissue

5.) The specimen is received in formalin, labeled "Distal margin of urethra" and consists of a 1.0 x 1.0 x 0.7 cm irregular, rubbery, tan-white tissue fragment, which is inked in black, sectioned and entirely submitted.

Summary of sections:

DMU - is the margin of urethra

6.) The specimen is received in formalin, labeled "Posterior vaginal wall" and consists of a 1.3 x 0.7 x 0.1 cm, irregular, firm, tan-white tissue fragment, which is submitted in toto.

Summary of sections:

PVW - posterior vaginal wall

7.) The specimen is received in formalin, labeled "Left ureter" and consists of an unoriented, 1.1 cm length and 0.3 cm in diameter segment of ureter circumferentially surrounded by 0.5 cm thick pink-white membranous tissue. The margins are inked in black and blue. The ureter is sectioned and entirely submitted.

Summary of sections:

LU - left ureter, sequential sections

8.) The specimen is received in formalin, labeled "Right ureter" and consists of an unoriented, 1.2 cm length and 0.6 cm in diameter edematous and slightly dilated portion of ureter circumferentially surrounded by 0.3 cm thick pink-white membranous tissue. The margins are inked in black and blue. The ureter is sectioned and entirely submitted. Also received in the same container is a 0.5 x 0.4 x 0.2 cm, soft, irregular, tan-white tissue fragment, which is submitted in toto.

Summary of sections:

RU - right ureter, sequential sections
ATF - additional tissue fragment

Summary of Sections:

Part 1: SP: Bladder, cervix, bilateral tubes and ovaries; Cystohysterectomy and bilateral salpingo-oophorectomy

Block	Sect. Site	PCs
-------	------------	-----

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

1	AC	1
4	ADD	4
1	AEM	1
1	DOM	1
1	F	1
7	L	7
1	LA	1
1	LO	1
1	LP	1
2	LT	2
1	LUM	1
1	LUO	1
1	PC	1
1	PEM	1
1	RA	1
1	RO	1
1	RP	1
2	RT	2
1	RUM	1
1	RUO	1
1	T	1
1	UTHM	1

Part 2: SP: Right pelvic lymph nodes; Dissection

Block	Sect. Site	PCs
4	BLN	6
2	LN	3
6	RSLN	6

Part 3: SP: Left pelvic lymph nodes; Dissection

Block	Sect. Site	PCs
3	BLN	4
2	LN	3
6	RSLN	6
5	SLN	5

Part 4: SP: Left peri-ureteral tissue; Excision

Block	Sect. Site	PCs
1	LPT	4

Part 5: SP: Distal margin of urethra; Excision

Block	Sect. Site	PCs
2	DMU	4

Part 6: SP: Posterior vaginal wall; Excision

Block	Sect. Site	PCs
1	PVW	1

Part 7: SP: Left ureter; Excision

Block	Sect. Site	PCs
2	LU	4

Part 8: SP: Right ureter; Excision

Block	Sect. Site	PCs
-------	------------	-----

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

1
2 ATF 1
RU 4

Source: NCI Genomic Data Commons file cbdda644-2d3d-47cf-989c-598323fc08b7 (TCGA-DK-A1AB.5FCDE7D1-8263-465D-B0A6-C660B152D86F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).